Gene-level copy-number profile of tumor specimen TARGET-10-PANSBR-09A from TARGET case TARGET-10-PANSBR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 20.6 years (7,519 days).
Specimen TARGET-10-PANSBR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.6311b0f4-5a36-5eb0-a160-ea9c1864e339.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PANSBR-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 362 have no estimate.
https://portal.gdc.cancer.gov/files/1f81a589-23c3-499d-92c1-1d20364ec9be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 2,476; copy number 2: 57,588; copy number 3: 106; copy number 4: 4; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:142,636,924–142,793,368, 26 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr11:64,185,272–64,357,534, 25 genes (within-gene range 0–2): STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2, CCDC88B, MIR7155.
- chr14:106,531,141–106,695,397, 34 genes: IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:3,009,976–3,013,111, 1 gene, copy number 5 (within-gene range 2–5): AL731533.1.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
